Gene-level copy-number profile of tumor specimen TCGA-YU-AA60-01A from TCGA case TCGA-YU-AA60, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 43.6 years (15,920 days).
Specimen TCGA-YU-AA60-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e67745d3-af08-46f3-8f0b-c6618f86cb9f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-YU-AA60-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/deff6f98-7d3f-4d7f-8e31-92bcd76e6d11

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 111; copy number 1: 1,666; copy number 2: 18,318; copy number 3: 19,519; copy number 4: 12,968; copy number 5: 2,824; copy number 6: 2,897; copy number 7: 324; copy number 8: 1; copy number 9: 49; copy number 10: 232.

Homozygous deletions (total copy number 0; autosomes only): 44 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:21,397,987–21,417,492, 3 genes: PPP1R11P1, AL592309.1, AL592309.2.
- chr5:58,198–58,915, 1 gene: AC113430.1.
- chr5:174,751,734–174,751,787, 1 gene (within-gene range 0–2): MIR4634.
- chr9:12,134–89,850, 7 genes: DDX11L5, WASHC1, MIR1302-9HG, MIR1302-9, FAM138C, AL449043.2, PGM5P3-AS1.
- chr9:41,890,314–42,714,539, 21 genes: CNTNAP3B, RBM17P3, CR788268.1, RN7SL343P, SPATA31A6, AL445584.1, FAM74A7, AL445584.3, AL445584.2, FKBP4P6, SDR42E1P2, ATP5F1AP1, RAB28P3, RBPJP6, BX088651.4, BX088651.1, BX088651.2, FGF7P5, BX088651.3, FGF7P4, BX664718.1.
- chr9:126,860,665–126,885,878, 1 gene: ZBTB34.
- chr11:135,061,781–135,075,908, 1 gene: LINC02684.
- chr13:100,027,769–100,028,174, 1 gene: NDUFA12P1.
- chr13:100,062,296–100,063,601, 1 gene: ASNSP3.
- chr18:49,560,699–49,599,185, 1 gene: LIPG.
- chr19:58,559,129–58,605,223, 6 genes: MZF1-AS1, MZF1, CENPBD1P1, AC016629.3, AC016629.1, AC016629.2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 606 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:52,622,458–73,915,010, 323 genes, copy number 7 (broad region; genes not listed).
- chr12:11,351,823–11,395,566, 1 gene, copy number 7 (within-gene range 6–7): PRB1.
- chr12:38,316,762–50,480,004, 281 genes, copy number 9–10 (broad region; genes not listed).
- chr21:13,305,152–13,314,944, 1 gene, copy number 8: AJ239318.1.

Autosomal genes at a single copy (total copy number 1): 1,221. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
